Gene-level copy-number profile of tumor specimen TCGA-AA-A02E-01A from TCGA case TCGA-AA-A02E, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IV; Age at diagnosis: 82.8 years (30,256 days).
Specimen TCGA-AA-A02E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.3d25618b-1f91-4562-9a7a-686a7be88b6c.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-A02E-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 399 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d1c6a22f-575d-4b9a-8719-1f17df9198aa

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 540; copy number 1: 5; copy number 2: 6,660; copy number 3: 17,592; copy number 4: 17,355; copy number 5: 11,781; copy number 6: 2,109; copy number 7: 2,710; copy number 9: 1,391; copy number 14: 5; copy number 15: 76.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-A02E-01A-01D-A008-01): tumor purity 0.68, ploidy 3.86, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:47,263,935–48,410,752, 17 genes (within-gene range 0–2): AC051635.1, MIR4527HG, MIR4527, AC102797.2, AC102797.1, TPMTP1, AC026898.1, SMAD2, MTCO2P2, AC120349.3, AC120349.1, AC120349.2, ZBTB7C, AC105101.1, AC105101.2, RNU6-708P, C18orf12.
- chr20:14,933,843–15,022,958, 3 genes: AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4,182 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:195,514,036–242,160,153, 943 genes, copy number 7 (broad region; genes not listed).
- chr6:6,534,697–7,620,878, 31 genes, copy number 7: CNN3P1, LY86, AL031123.2, AL031123.3, AL031123.1, AL031123.4, AL031123.5, AL136361.1, BTF3P7, AL158817.1, RN7SL554P, AL139390.1, RREB1, AL355336.1, Y_RNA, AL589644.1, AL139095.5, SSR1, AL139095.4, CAGE1, AL139095.1, AL139095.2, AL139095.3, RIOK1, HNRNPLP1, AL138878.1, AL138878.2, AL031058.1, DSP, SNRNP48, AL390026.1.
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 7 (broad region; genes not listed).
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 9 (broad region; genes not listed).
- chr19:13,206,442–14,031,557, 23 genes, copy number 15 (within-gene range 5–15): CACNA1A, CCDC130, MRI1, AC008686.1, C19orf53, ZSWIM4, AC020916.2, RN7SL619P, AC020916.1, MIR24-2, MIR27A, MIR23A, NANOS3, MIR181C, MIR181D, C19orf57, CC2D1A, PODNL1, DCAF15, RFX1, AC022098.4, RLN3, AC022098.2.
- chr19:29,606,283–29,824,312, 5 genes, copy number 14: POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1.
- chr19:39,083,913–39,846,379, 53 genes, copy number 15: ACP7, PAK4, AC011443.1, NCCRP1, SYCN, IFNL3P1, IFNL3, IFNL4, MSRB1P1, IFNL4P1, IFNL2, IFNL1, LRFN1, GMFG, AC011445.1, SAMD4B, RN7SL566P, PAF1, MED29, ZFP36, MIR4530, PLEKHG2, RPS16, SUPT5H, TIMM50, DLL3, SELENOV, EID2B, AC011500.3, TDGF1P7, EID2, AC011500.2, AC011500.1, RPS29P24, RPS29P25, RPS29P26, LGALS13, AC005176.2, AC005176.1, RPS29P30, LGALS16, LGALS17A, AC005515.1, AC093063.1, RPS29P27, LGALS14, AC006133.1, CLC, LEUTX, AC005393.1, DYRK1B, MIR6719, FBL.
- chr20:53,668,697–62,873,076, 189 genes, copy number 7 (broad region; genes not listed).
- chr22:25,279,529–25,520,854, 13 genes, copy number 7 (within-gene range 4–7): AL022332.1, AL022324.4, AL022332.2, IGLL3P, AL022324.1, AL022324.2, LRP5L, AL022324.3, AL008721.1, IGLVIVOR22-1, CRYBB2P1, MIR6817, AL008721.2.

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
